Gene-level copy-number profile of tumor specimen TCGA-N5-A4RO-01A from TCGA case TCGA-N5-A4RO, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 68.0 years (24,823 days).
Specimen TCGA-N5-A4RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.07845351-b136-4ce9-ac2e-9218adb85194.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6fce09e-46d0-46d6-b407-cb9feed5dfe6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 3,152; copy number 2: 23,907; copy number 3: 27,985; copy number 4: 3,451; copy number 5: 825; copy number 6: 141; copy number 7: 8; copy number 8: 12; copy number 9: 69; copy number 10: 53; copy number 11: 27; copy number 12: 12; copy number 13: 57; copy number 15: 72; copy number 19: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RO-01A-11D-A28Q-01): tumor purity 0.93, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,107,412–26,253,710, 26 genes: H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9.
- chr11:79,092,848–79,098,003, 1 gene: AP002957.1.
- chr11:88,408,179–88,428,176, 2 genes: GAPDHP70, AP003120.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 280 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:14,803,666–14,906,586, 1 gene, copy number 7 (within-gene range 4–7): C12orf60.
- chr12:14,880,864–15,006,999, 5 genes, copy number 7: MGP, ERP27, ARHGDIB, PDE6H, LINC01489.
- chr13:104,814,327–106,942,561, 26 genes, copy number 7–19: RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3.
- chr19:27,638,483–31,349,436, 72 genes, copy number 9–13 (within-gene range 5–13) (broad region; genes not listed).
- chr20:31,274,170–32,335,011, 53 genes, copy number 10 (within-gene range 5–10): DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B.
- chr20:41,331,123–41,360,582, 2 genes, copy number 12: ADI1P1, LPIN3.
- chr20:44,302,840–46,550,654, 109 genes, copy number 11–15 (broad region; genes not listed).
- chr20:47,071,865–47,656,877, 12 genes, copy number 8 (within-gene range 5–8): AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3.

Autosomal genes at a single copy (total copy number 1): 1,893. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
